Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040033-09A.2 (aliquot TARGET-15-SJMPAL040033-09A.2-01D) from TARGET case TARGET-15-SJMPAL040033, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,242 days).
Specimen TARGET-15-SJMPAL040033-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1972b712-6719-4de3-92a6-602a22fce5e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040033-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040033-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83063a1c-aa3a-443c-be72-114c749b0ee8

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs199916575, COSV66069988; called by muse, mutect2, varscan2
- CERS3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761591750, COSV52569608; called by muse, mutect2, varscan2
- CFAP61 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV55618034, COSV55618947; called by muse, varscan2
- INSC | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs751225472; called by muse, varscan2
- NDST1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs770142868; called by muse, mutect2, varscan2
- NRSN1 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV65893779; called by muse, mutect2
- PLSCR4 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61607453; called by muse, mutect2, varscan2
- SCML1 | c.643C>T p.R215W (on ENST00000380041 / NM_001037540.3; = p.R188W on NM_006746.6) | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101193977; called by muse, mutect2, varscan2
- ZNF469 | c.5521C>T p.R1841W (on ENST00000437464; = p.R1869W on NM_001367624.2) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1292024809, COSV101458687; called by muse, mutect2, varscan2
- GUCY1B1 | c.1374C>A p.D458E | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR7D2 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SPI1 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TEF | c.713C>A p.T238K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, mutect2
- FEM1C | c.1563G>A p.V521= | Silent (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- HTR5A | c.249C>A p.A83= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV55281579, COSV99839563; called by muse, mutect2
- KRT15 | c.1273+34G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
